CCDI case PBBNMV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/7a4efb35-9adc-4c52-97c7-cbf313be7233

Demographics
Sex at birth: female; Race: native hawaiian or other pacific islander; Vital status: Dead.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 7.9 years (2,890 days).

Biospecimens (3 samples)
- Sample 0DD6QU: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DD6QV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DD6QW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
